Surgical pathology report (de-identified scan), TCGA case TCGA-HT-A74K, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-A74K-01A (Primary Tumor).

Pathology Report for

Date of Surgery:

Diagnosis:

Right frontal lobe tumor

Anaplastic oligodendroglioma, grade III

- MIB-1 LI = 12.7%

Discussion:

Numerous MIB-1 reactive cells are throughout the tumor. In the most proliferative area, a labeling index of 12.7% is calculated.

Microscopic Description:

Sections reveal a hypercellular glial neoplasm. The tumor cells exhibit round to oval, hyperchromatic nuclei with moderate nuclear atypia. On the frozen material, most of the cells exhibit perinuclear halos. Foci of significant microvascular proliferation are seen. Scattered foci of necrosis are encountered. Dystrophic calcification is noted. Up to 3 mitotic figures per 10 high power fields are encountered. These features are consistent with high grade glioma.

II D-0-3
Oligodendroglioma, grade III
CCKF 9451/3
Site Brain, supratentorial NOS
path Q 71.0
② Brain, frontal lobe
Q 71.1
JW 8/27/13

Source: NCI Genomic Data Commons file 127544e8-a646-4bdb-9aa3-4baee31ef15b (TCGA-HT-A74K.CB30199B-FBD0-494A-8A61-5B58E5D61BB9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).